Somatic mutation profile of tumor specimen TCGA-BA-5557-01A (aliquot TCGA-BA-5557-01A-01D-1512-08) from TCGA case TCGA-BA-5557, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 41.7 years (15,247 days).
Specimen TCGA-BA-5557-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c1ae2cc-b776-4a13-9afd-704c24caba2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5557-10A (Blood Derived Normal), aliquot TCGA-BA-5557-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a98c5a8-f1b2-45cd-8573-762c5e3d462a

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 21, Silent 12, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519881, COSV58689512, COSV58690350, COSV58703585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV100771815; called by muse, mutect2
- CCDC116 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as rs774127975, COSV53038694; called by muse, mutect2, varscan2
- CDC42EP1 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99312398; called by muse, varscan2
- CLCN4 | c.2267C>A p.S756Y | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101073657; called by muse, mutect2
- DNAAF3 | c.1553C>T p.S518L (on ENST00000524407 / NM_001256715.2; = p.S565L on NM_178837.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100787850; called by muse, mutect2, varscan2
- DNAJB7 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV53421246; called by muse, mutect2
- ERAP2 | c.849+2T>A p.X283_splice | Splice Site (SNP) | VAF 16/107 reads (15%) | catalogued as COSV101163503; called by muse, mutect2, varscan2
- HCLS1 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.224); catalogued as COSV100100350; called by muse, mutect2, varscan2
- HUWE1 | c.11311G>A p.E3771K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV53356677; called by muse, mutect2, varscan2
- KAZN | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1421621626, COSV63209624; called by muse, mutect2
- OR52E2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs745479340, COSV58612078, COSV58612463; called by mutect2, varscan2
- PAPOLB | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as COSV101271270, COSV101271514; called by muse, mutect2
- PCDHB13 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53393831; called by muse, mutect2, varscan2
- PITPNC1 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100082865; called by muse, mutect2
- PITPNM2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54897209; called by muse, mutect2, varscan2
- PLOD2 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs905903603, COSV51467387; called by muse, mutect2, varscan2
- PRKRIP1 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1299640797, COSV100700310; called by muse, varscan2
- SLC4A4 | c.2995C>A p.L999I (on ENST00000264485 / NM_001098484.3; = p.L955I on NM_003759.4) | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99138966; called by muse, mutect2, varscan2
- TMEM120B | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99932176; called by muse, mutect2, varscan2
- TP53 | c.602T>A p.L201* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV52837759, COSV53037685; called by muse, mutect2, varscan2
- VBP1 | c.524-1G>C p.X175_splice | Splice Site (SNP) | VAF 10/230 reads (4%) | catalogued as COSV53973619; called by muse, mutect2
- WNK3 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100670794; called by muse, mutect2
- NR2C2 | c.1446G>A p.M482I (on ENST00000393102; = p.M501I on NM_003298.5) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.132); called by muse, mutect2
- ABCC11 | c.3357C>T p.V1119= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV62321411; called by muse, mutect2
- AP002748.5 | c.174G>A p.S58= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as COSV100567685; called by muse, mutect2
- GRAMD1B | c.1471C>A p.R491= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV100454305; called by muse, mutect2
- HEPH | c.1077A>C p.A359= (on ENST00000343002; = p.A92= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100294128; called by mutect2, varscan2
- JAG1 | c.2049C>T p.R683= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as rs1389234825, COSV99652439; called by muse, mutect2, varscan2
- KCNA6 | c.901T>C p.L301= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs775356647, COSV99768339; called by muse, mutect2, varscan2
- PPP1R12C | c.483C>T p.A161= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs747129085; called by muse, mutect2, varscan2
- PZP | c.2193G>T p.G731= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV99736210; called by muse, mutect2, varscan2
- SEPTIN6 | c.207G>A p.G69= | Silent (SNP) | VAF 85/421 reads (20%) | catalogued as COSV100595378; called by muse, mutect2, varscan2
- TGFB2 | c.897G>A p.R299= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs1301204369, COSV65111776; called by muse, mutect2
- TTN | c.960T>C p.S320= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100594870; called by muse, mutect2, varscan2
- ZNF232 | c.543G>A p.E181= | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as COSV100005515; called by muse, mutect2
